Somatic mutation profile of tumor specimen 0DS533 from CCDI case PBCHTC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 11.8 years (4,298 days).
Specimen 0DS533: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f63dcf6-91ec-441f-a124-0dd2fec61ec9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DS545 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ee496c0-030c-47db-a95f-8138a1eb039c

The open-access MAF lists 55 somatic variants for this specimen: 30 protein-altering or splice-affecting, 13 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 13, Intron 8, Frame Shift Del 4, 3'UTR 3, Nonsense Mutation 1, Splice Site 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 241/431 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs104894228, CM060018, COSV54236651, COSV54236730, COSV54241641; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP10B | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 150/457 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs773547506, COSV58779946; called by muse, mutect2, varscan2
- BCOR | c.4200del p.P1401Rfs*83 (on ENST00000378444 / NM_001123385.2; = p.P1367Rfs*83 on NM_017745.6) | Frame Shift Del (DEL) | VAF 104/201 reads (52%) | catalogued as CD095798; called by mutect2, pindel, varscan2
- CCDC102B | c.1211C>T p.S404F | Missense Mutation (SNP) | VAF 109/380 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as COSV60134667; called by muse, mutect2, varscan2
- CHPF | c.1990C>T p.R664C | Missense Mutation (SNP) | VAF 144/661 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs776333654; called by muse, mutect2, varscan2
- CNTNAP5 | c.2344C>G p.R782G | Missense Mutation (SNP) | VAF 21/843 reads (2%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.492); catalogued as COSV70476949; called by muse, mutect2
- DNMT1 | c.3475+6C>T | Splice Region (SNP) | VAF 87/347 reads (25%) | catalogued as rs372240993; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPX | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 171/566 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs201419733, COSV56597895; called by muse, mutect2, varscan2
- FAM237A | c.140C>A p.P47H | Missense Mutation (SNP) | VAF 156/854 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.244); catalogued as COSV69305396; called by muse, mutect2, varscan2
- JADE2 | c.676G>A p.V226M | Missense Mutation (SNP) | VAF 148/436 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99252972; called by muse, mutect2, varscan2
- MYOG | c.303del p.F101Lfs*4 | Frame Shift Del (DEL) | VAF 94/374 reads (25%) | catalogued as COSV54095162; called by mutect2, pindel, varscan2
- NSMF | c.866G>C p.R289P (on ENST00000371475 / NM_001130969.3; = p.R287P on NM_015537.4) | Missense Mutation (SNP) | VAF 117/324 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV55809950; called by muse, mutect2, varscan2
- NTN5 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 95/351 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as rs1215972971; called by muse, mutect2, varscan2
- PRR12 | c.2663C>A p.T888K (on ENST00000615927; = p.T1709K on NM_020719.3) | Missense Mutation (SNP) | VAF 126/421 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV101330760; called by mutect2, varscan2
- RBBP6 | c.3538C>G p.P1180A | Missense Mutation (SNP) | VAF 247/759 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.232); catalogued as COSV100154893; called by muse, mutect2, varscan2
- TGS1 | c.1832G>A p.R611H | Missense Mutation (SNP) | VAF 94/345 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.12); catalogued as rs765862127; called by muse, mutect2, varscan2
- AK7 | c.1974G>T p.W658C | Missense Mutation (SNP) | VAF 111/318 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C2CD4A | c.866C>G p.A289G | Missense Mutation (SNP) | VAF 114/343 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CHPF2 | c.1388C>A p.A463D | Missense Mutation (SNP) | VAF 63/286 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- FN1 | c.6470C>A p.A2157D (on ENST00000359671 / NM_001365524.2; = p.A2126D on NM_002026.4) | Missense Mutation (SNP) | VAF 105/517 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HDAC2 | c.238A>G p.I80V | Missense Mutation (SNP) | VAF 96/365 reads (26%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); called by muse, mutect2
- LMNTD1 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 141/400 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NCBP1 | c.1677del p.F559Lfs*18 | Frame Shift Del (DEL) | VAF 99/434 reads (23%) | called by mutect2, pindel, varscan2
- OR56A3 | c.352A>G p.T118A | Missense Mutation (SNP) | VAF 139/585 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- PHF14 | c.2222T>A p.L741* | Nonsense Mutation (SNP) | VAF 105/450 reads (23%) | called by muse, mutect2, varscan2
- SPEG | c.2326_2327del p.R776Afs*86 | Frame Shift Del (DEL) | VAF 104/667 reads (16%) | called by mutect2, pindel, varscan2
- TCTE3 | c.56C>T p.T19I | Missense Mutation (SNP) | VAF 226/618 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TPH2 | c.609-2A>G p.X203_splice | Splice Site (SNP) | VAF 61/170 reads (36%) | called by muse, mutect2, varscan2
- USP37 | c.1821T>G p.S607R | Missense Mutation (SNP) | VAF 165/881 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- ZNF395 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 102/463 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASTN1 | c.3783C>T p.Y1261= | Silent (SNP) | VAF 90/374 reads (24%) | catalogued as rs767306251; called by muse, mutect2, varscan2
- CDH12 | c.2019C>T p.F673= | Silent (SNP) | VAF 187/494 reads (38%) | catalogued as rs775446101, COSV66385898; called by muse, mutect2, varscan2
- CDX1 | c.210C>T p.D70= | Silent (SNP) | VAF 21/491 reads (4%) | called by muse, mutect2
- CES5A | c.1530A>G p.P510= (on ENST00000290567 / NM_001143685.2; = p.P460= on NM_145024.3) | Silent (SNP) | VAF 150/466 reads (32%) | catalogued as rs958211764; called by muse, mutect2
- GALP | c.246G>A p.Q82= | Silent (SNP) | VAF 103/357 reads (29%) | catalogued as COSV62000635; called by muse, mutect2, varscan2
- HHIPL1 | c.2148G>T p.L716= | Silent (SNP) | VAF 86/254 reads (34%) | called by muse, mutect2
- HIVEP2 | c.1455C>T p.V485= | Silent (SNP) | VAF 104/348 reads (30%) | catalogued as rs202218400, COSV50042789; called by muse, mutect2, varscan2
- LRRK2 | c.3819G>C p.L1273= | Silent (SNP) | VAF 125/421 reads (30%) | catalogued as COSV100108706; called by muse, mutect2, varscan2
- ROGDI | c.6C>T p.A2= | Silent (SNP) | VAF 70/229 reads (31%) | catalogued as rs781663118; called by muse, mutect2, varscan2
- SLC4A1AP | c.1614G>A p.A538= | Silent (SNP) | VAF 189/716 reads (26%) | catalogued as rs116617546, COSV58136873; called by muse, mutect2, varscan2
- TP53BP2 | c.1812C>T p.F604= (on ENST00000343537 / NM_001031685.3; = p.F475= on NM_005426.2) | Silent (SNP) | VAF 197/799 reads (25%) | called by muse, mutect2, varscan2
- TRPV5 | c.1329G>A p.R443= | Silent (SNP) | VAF 168/678 reads (25%) | called by muse, mutect2, varscan2
- ZNF423 | c.1656C>A p.G552= (on ENST00000563137 / NM_001379286.1; = p.G544= on NM_015069.4) | Silent (SNP) | VAF 95/404 reads (24%) | called by muse, mutect2, varscan2
- AC139769.1 | n.214-4494G>T | Intron (SNP) | VAF 28/129 reads (22%) | called by mutect2, varscan2
- ANPEP | c.897+61G>A | Intron (SNP) | VAF 70/277 reads (25%) | catalogued as rs1013402247; called by muse, mutect2, varscan2
- CA14 | c.562+42T>A | Intron (SNP) | VAF 66/273 reads (24%) | called by muse, mutect2, varscan2
- CCDC159 | c.-11C>G | 5'UTR (SNP) | VAF 98/416 reads (24%) | called by muse, mutect2, varscan2
- CDC14B | c.161-1375G>A | Intron (SNP) | VAF 68/181 reads (38%) | called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.2463+1228T>G | Intron (SNP) | VAF 94/280 reads (34%) | called by muse, mutect2, varscan2
- GPBP1 | c.479-87T>A | Intron (SNP) | VAF 9/39 reads (23%) | catalogued as rs1002773050; called by muse, mutect2
- MLANA | c.*90A>G | 3'UTR (SNP) | VAF 49/107 reads (46%) | called by muse, mutect2, varscan2
- MYH7B | c.*76C>T | 3'UTR (SNP) | VAF 74/369 reads (20%) | catalogued as rs1166476760; called by muse, mutect2, varscan2
- RFC5 | c.793+32G>A | Intron (SNP) | VAF 60/178 reads (34%) | called by muse, mutect2, varscan2
- SCRN3 | c.*78T>C | 3'UTR (SNP) | VAF 39/161 reads (24%) | called by muse, mutect2, varscan2
- UBE3C | c.2481+14C>T | Intron (SNP) | VAF 97/356 reads (27%) | catalogued as rs953255596; called by muse, mutect2, varscan2
